Somatic mutation profile of tumor specimen TCGA-60-2722-01A (aliquot TCGA-60-2722-01A-01W-0877-08) from TCGA case TCGA-60-2722, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 66.4 years (24,267 days).
Specimen TCGA-60-2722-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21b341c2-02cc-45be-8723-6e6a953b02a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-60-2722-11A (Solid Tissue Normal), aliquot TCGA-60-2722-11A-01D-1522-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0dbc3df5-46be-4443-9e0a-3f7f5cb47f70

The open-access MAF lists 333 somatic variants for this specimen: 259 protein-altering or splice-affecting, 68 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 68, Nonsense Mutation 18, Frame Shift Del 9, Splice Site 6, Translation Start Site 2, Frame Shift Ins 2, RNA 2, 3'UTR 1, Intron 1, Splice Region 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1513C>G p.R505G (on ENST00000281708 / NM_001349798.2; = p.R425G on NM_018315.5) | Missense Mutation (SNP) | VAF 71/101 reads (70%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149680468, COSV55890969, COSV55891274, COSV55898451; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 56/66 reads (85%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACAN | c.2308G>A p.E770K | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV61356492; called by mutect2, varscan2
- ACIN1 | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 319/676 reads (47%) | catalogued as COSV52973529; called by muse, mutect2, varscan2
- ADAMTS3 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 137/632 reads (22%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV54385585; called by muse, mutect2, varscan2
- ADAR | c.490A>T p.K164* | Nonsense Mutation (SNP) | VAF 247/535 reads (46%) | catalogued as COSV52712412; called by muse, mutect2, varscan2
- ADAR | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 87/203 reads (43%) | SIFT tolerated (1); PolyPhen possibly damaging (0.601); catalogued as COSV52712430; called by muse, mutect2, varscan2
- ADGRD1 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs147105264; called by muse, mutect2, varscan2
- ADGRL4 | c.337G>T p.A113S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); catalogued as COSV66059509, COSV66059584; called by muse, mutect2, varscan2
- ADNP2 | c.104T>G p.L35R | Missense Mutation (SNP) | VAF 33/80 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV51536316; called by muse, mutect2, varscan2
- ANK3 | c.8757G>T p.M2919I | Missense Mutation (SNP) | VAF 17/31 reads (55%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); catalogued as COSV55045171; called by muse, mutect2, varscan2
- ANKRD50 | c.1169A>G p.D390G | Missense Mutation (SNP) | VAF 4/98 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.134); catalogued as COSV72385078; called by muse, mutect2
- AP2B1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 141/275 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs763030515, COSV51997193; called by muse, mutect2, varscan2
- APOBR | c.947G>C p.G316A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.021); catalogued as COSV60488819; called by muse, varscan2
- ARHGAP11A | c.2750C>T p.S917L | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as COSV55705267; called by muse, mutect2, varscan2
- ARHGAP12 | c.1633-2A>T p.X545_splice | Splice Site (SNP) | VAF 21/70 reads (30%) | catalogued as COSV60961486; called by muse, mutect2, varscan2
- ARHGEF15 | c.135A>T p.E45D | Missense Mutation (SNP) | VAF 20/27 reads (74%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV62724395; called by muse, mutect2, varscan2
- ASB9 | c.559C>G p.L187V | Missense Mutation (SNP) | VAF 77/92 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66851303; called by muse, mutect2, varscan2
- ATAD3A | c.1192A>T p.M398L | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV59231855; called by muse, mutect2, varscan2
- ATF4 | c.429T>A p.H143Q | Missense Mutation (SNP) | VAF 78/144 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV57477642; called by muse, mutect2, varscan2
- ATG10 | c.560A>G p.N187S | Missense Mutation (SNP) | VAF 112/185 reads (61%) | SIFT deleterious (0); PolyPhen benign (0.368); catalogued as rs1358378459, COSV56422766; called by muse, mutect2, varscan2
- ATP6V1B1 | c.785+1G>T p.X262_splice | Splice Site (SNP) | VAF 50/103 reads (49%) | catalogued as CS991327, COSV52268252, COSV99314101; called by muse, mutect2, varscan2
- ATXN3 | c.388-1G>A p.X130_splice | Splice Site (SNP) | VAF 120/277 reads (43%) | catalogued as COSV61493760; called by muse, mutect2, varscan2
- BAIAP2L2 | c.234G>A p.M78I | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.16); catalogued as COSV59268061; called by muse, mutect2, varscan2
- BBS9 | c.190C>G p.Q64E | Missense Mutation (SNP) | VAF 73/153 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.026); catalogued as rs769256027, CM111654, COSV54157315; called by muse, mutect2, varscan2
- BEST3 | c.1735G>A p.E579K | Missense Mutation (SNP) | VAF 52/88 reads (59%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.036); catalogued as rs867886404, COSV58298930; called by muse, mutect2, varscan2
- BNIP1 | c.271A>C p.N91H | Missense Mutation (SNP) | VAF 58/74 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.258); catalogued as COSV51570004; called by muse, mutect2, varscan2
- BSN | c.4390C>T p.P1464S | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV56513275, COSV56516741; called by muse, mutect2, varscan2
- C1QA | c.682C>T p.Q228* | Nonsense Mutation (SNP) | VAF 9/51 reads (18%) | catalogued as COSV101009437, COSV65889265; called by muse, mutect2, varscan2
- C6 | c.2664C>A p.C888* | Nonsense Mutation (SNP) | VAF 46/218 reads (21%) | catalogued as COSV54705373; called by muse, mutect2, varscan2
- CAMK1G | c.1069G>A p.E357K | Missense Mutation (SNP) | VAF 141/366 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs760816448, COSV50520281; called by muse, mutect2, varscan2
- CARMIL1 | c.694A>G p.T232A | Missense Mutation (SNP) | VAF 361/413 reads (87%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV61513944; called by muse, mutect2, varscan2
- CAVIN4 | c.255C>G p.I85M | Missense Mutation (SNP) | VAF 261/305 reads (86%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV100293073, COSV56866583; called by muse, mutect2, varscan2
- CCDC102B | c.838G>T p.A280S | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.82); PolyPhen benign (0.01); catalogued as COSV60134990; called by muse, mutect2, varscan2
- CCDC63 | c.1365C>A p.N455K | Missense Mutation (SNP) | VAF 25/111 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.915); catalogued as COSV57526959; called by muse, mutect2, varscan2
- CCSER1 | c.583G>T p.V195F | Missense Mutation (SNP) | VAF 139/231 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.387); catalogued as COSV61409374; called by muse, mutect2, varscan2
- CD22 | c.2425A>C p.N809H | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50049702; called by muse, mutect2, varscan2
- CDH10 | c.751G>C p.G251R | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52570779, COSV52574921; called by muse, mutect2, varscan2
- CEP170 | c.1877G>T p.R626I | Missense Mutation (SNP) | VAF 78/96 reads (81%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as COSV60506305, COSV60510655; called by muse, mutect2, varscan2
- CERK | c.424G>T p.G142* | Nonsense Mutation (SNP) | VAF 73/122 reads (60%) | catalogued as COSV53450148; called by muse, mutect2, varscan2
- CFAP70 | c.1755C>A p.Y585* | Nonsense Mutation (SNP) | VAF 37/157 reads (24%) | catalogued as COSV60281114; called by muse, mutect2, varscan2
- CFH | c.1430G>A p.C477Y | Missense Mutation (SNP) | VAF 34/143 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66405949; called by muse, mutect2, varscan2
- CHD9 | c.4688G>T p.G1563V | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54607871; called by muse, mutect2, varscan2
- CHRD | c.2551C>T p.P851S | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52605649; called by muse, mutect2, varscan2
- CNGB3 | c.64C>A p.Q22K | Missense Mutation (SNP) | VAF 160/269 reads (59%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as COSV60685043; called by muse, mutect2, varscan2
- CNOT1 | c.3392C>T p.S1131L | Missense Mutation (SNP) | VAF 102/278 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV55313247; called by muse, mutect2, varscan2
- CNTNAP5 | c.3628G>C p.V1210L | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.058); catalogued as COSV70473984; called by muse, mutect2, varscan2
- COL11A1 | c.3833G>C p.R1278T | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.977); catalogued as rs1484726432, COSV62173704, COSV62182589; called by muse, mutect2, varscan2
- COL22A1 | c.2152C>A p.P718T | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.175); catalogued as COSV57324289; called by muse, mutect2, varscan2
- COL24A1 | c.3574T>A p.Y1192N | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.41); catalogued as COSV65302310; called by muse, mutect2, varscan2
- COL4A4 | c.3091C>A p.P1031T | Missense Mutation (SNP) | VAF 90/147 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.129); catalogued as COSV61629739; called by muse, mutect2, varscan2
- COL4A4 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 94/279 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs770011392, COSV61629745; called by muse, mutect2, varscan2
- COL6A3 | c.7832C>A p.A2611E | Missense Mutation (SNP) | VAF 216/421 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV55080355, COSV55089770, COSV55094724; called by muse, mutect2, varscan2
- COL9A1 | c.1370G>C p.G457A | Missense Mutation (SNP) | VAF 15/18 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100295485, COSV57878956; called by muse, mutect2, varscan2
- CPS1 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51802685; called by muse, mutect2, varscan2
- CPS1 | c.2792T>G p.L931R | Missense Mutation (SNP) | VAF 80/151 reads (53%) | SIFT tolerated (0.22); PolyPhen benign (0.105); catalogued as COSV51802695; called by muse, mutect2, varscan2
- CPXCR1 | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 35/37 reads (95%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV52161128; called by muse, mutect2, varscan2
- CSMD2 | c.7544G>A p.G2515D | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53882310; called by muse, mutect2, varscan2
- CUBN | c.6487T>A p.S2163T | Missense Mutation (SNP) | VAF 46/84 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV64708376; called by muse, mutect2, varscan2
- DAGLB | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.023); catalogued as COSV51702351; called by muse, mutect2, varscan2
- DCAF12L2 | c.1342G>C p.G448R | Missense Mutation (SNP) | VAF 46/50 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1208978421, COSV63580369; called by muse, mutect2, varscan2
- DDB2 | c.1024-1G>A p.X342_splice | Splice Site (SNP) | VAF 36/46 reads (78%) | catalogued as COSV57037179; called by muse, mutect2, varscan2
- DEFA4 | c.223A>C p.T75P | Missense Mutation (SNP) | VAF 59/82 reads (72%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.529); catalogued as COSV52404458; called by muse, mutect2, varscan2
- DESI1 | c.130C>T p.H44Y | Missense Mutation (SNP) | VAF 41/68 reads (60%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54354030; called by muse, mutect2, varscan2
- DHTKD1 | c.169G>T p.A57S | Missense Mutation (SNP) | VAF 166/326 reads (51%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV53801828; called by muse, mutect2, varscan2
- DMD | c.5623A>C p.I1875L | Missense Mutation (SNP) | VAF 76/90 reads (84%) | SIFT tolerated (0.29); PolyPhen benign (0.043); catalogued as COSV63736054; called by muse, mutect2, varscan2
- DNAH11 | c.6110T>A p.V2037E | Missense Mutation (SNP) | VAF 74/173 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.549); catalogued as COSV60941189; called by muse, mutect2, varscan2
- DPYD | c.732G>T p.E244D | Missense Mutation (SNP) | VAF 68/144 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.515); catalogued as COSV64591434; called by muse, varscan2
- DUXA | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 39/78 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs145101590; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.2623T>A p.Y875N | Missense Mutation (SNP) | VAF 109/267 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57514606; called by muse, mutect2, varscan2
- EIF5A2 | c.203A>C p.K68T | Missense Mutation (SNP) | VAF 57/214 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.958); catalogued as COSV55542452; called by muse, mutect2, varscan2
- FAM135B | c.2914G>T p.V972L | Missense Mutation (SNP) | VAF 48/310 reads (15%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); catalogued as COSV52706722; called by muse, mutect2, varscan2
- FAM135B | c.1942C>A p.L648M | Missense Mutation (SNP) | VAF 128/207 reads (62%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.641); catalogued as COSV52706750; called by muse, mutect2, varscan2
- FAM216B | c.61C>T p.R21* | Nonsense Mutation (SNP) | VAF 60/142 reads (42%) | catalogued as rs1853636; called by muse, mutect2, varscan2
- FAM83E | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.141); catalogued as rs756248260, COSV52374594; called by muse, mutect2, varscan2
- FBXO30 | c.125A>T p.H42L | Missense Mutation (SNP) | VAF 124/154 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52790262; called by muse, mutect2, varscan2
- FBXO33 | c.451G>C p.G151R | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.379); catalogued as rs775184549, COSV53233332, COSV53235270; called by muse, mutect2, varscan2
- FCRL1 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 258/523 reads (49%) | catalogued as COSV63823939, COSV63825299; called by muse, mutect2, varscan2
- FER1L6 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 100/399 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.06); catalogued as COSV67548253, COSV67552175; called by muse, mutect2, varscan2
- FLNC | c.3932C>T p.T1311I | Missense Mutation (SNP) | VAF 37/90 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs1183933254, COSV57950874; called by muse, mutect2, varscan2
- FRAS1 | c.3451C>A p.L1151I | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV53591230; called by muse, mutect2, varscan2
- FRMPD2 | c.2393A>G p.Q798R | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0.021); catalogued as rs376247926; called by muse, mutect2
- GABRA1 | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 71/93 reads (76%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.953); catalogued as COSV50099010; called by muse, mutect2, varscan2
- GAL3ST1 | c.191G>T p.R64L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV58891936; called by muse, varscan2
- GCFC2 | c.968A>G p.Y323C | Missense Mutation (SNP) | VAF 70/158 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58079654; called by muse, mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 15/52 reads (29%) | catalogued as rs749150409; called by mutect2, varscan2
- GOLGB1 | c.1804G>T p.E602* | Nonsense Mutation (SNP) | VAF 33/120 reads (28%) | catalogued as COSV61462021; called by muse, mutect2, varscan2
- GOLGB1 | c.1803G>C p.M601I | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61462026; called by muse, mutect2, varscan2
- GPM6A | c.809C>A p.S270Y | Missense Mutation (SNP) | VAF 107/138 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54533147; called by muse, mutect2, varscan2
- GPR137C | c.539T>C p.V180A | Missense Mutation (SNP) | VAF 292/781 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV58704019; called by muse, mutect2, varscan2
- GPR158 | c.2230C>T p.R744W | Missense Mutation (SNP) | VAF 69/359 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs1157039977, COSV66265734; called by muse, mutect2, varscan2
- GRID1 | c.2426G>T p.G809V | Missense Mutation (SNP) | VAF 47/120 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60014983, COSV60019952; called by muse, mutect2, varscan2
- GRID1 | c.2425G>T p.G809C | Missense Mutation (SNP) | VAF 47/124 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV60014928; called by muse, mutect2, varscan2
- GSR | c.1195G>C p.E399Q | Missense Mutation (SNP) | VAF 45/74 reads (61%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.531); catalogued as COSV55319424, COSV55323737; called by muse, mutect2, varscan2
- GYS2 | c.2000G>A p.R667K | Missense Mutation (SNP) | VAF 43/81 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.079); catalogued as COSV53920725; called by muse, mutect2, varscan2
- HAPLN1 | c.873G>T p.Q291H | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.174); catalogued as COSV57145547; called by muse, mutect2, varscan2
- HAUS4 | c.395A>G p.Q132R | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs761536848, COSV52826748; called by muse, mutect2, varscan2
- HECTD4 | c.10672G>A p.E3558K | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.209); catalogued as COSV66386971; called by muse, mutect2
- HECW1 | c.3201C>G p.H1067Q | Missense Mutation (SNP) | VAF 163/423 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.886); catalogued as COSV67822484; called by muse, mutect2, varscan2
- HIF3A | c.1742A>T p.D581V (on ENST00000377670 / NM_152795.4; = p.D512V on NM_022462.4) | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); catalogued as COSV52195932; called by muse, mutect2, varscan2
- HNRNPCL1 | c.446C>G p.S149* | Nonsense Mutation (SNP) | VAF 76/304 reads (25%) | catalogued as COSV58610048, COSV58611487; called by muse, mutect2, varscan2
- HOXD1 | c.648G>C p.K216N | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100514124, COSV58923106; called by muse, mutect2, varscan2
- HPS3 | c.2773C>G p.H925D | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV56052807; called by muse, mutect2, varscan2
- HSPA13 | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV53464617; called by muse, mutect2, varscan2
- IBTK | c.3025+1G>T p.X1009_splice | Splice Site (SNP) | VAF 148/254 reads (58%) | catalogued as COSV60390999; called by muse, mutect2, varscan2
- IFT80 | c.932C>G p.T311R | Missense Mutation (SNP) | VAF 132/899 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV58445563; called by muse, mutect2, varscan2
- IL3 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 76/88 reads (86%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.818); catalogued as COSV57308434; called by muse, mutect2, varscan2
- IL37 | c.443A>G p.E148G | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.266); catalogued as COSV54490047; called by muse, mutect2, varscan2
- IRAK3 | c.1013T>A p.L338Q | Missense Mutation (SNP) | VAF 14/190 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV54159463; called by muse, mutect2
- JMJD1C | c.6882A>T p.E2294D | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.039); catalogued as COSV59512938; called by muse, mutect2, varscan2
- JPH1 | c.920A>G p.E307G | Missense Mutation (SNP) | VAF 74/122 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV60608776; called by muse, varscan2
- KALRN | c.7313T>C p.V2438A (on ENST00000360013 / NM_001024660.4; = p.V741A on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 84/170 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); catalogued as COSV52250206; called by muse, mutect2, varscan2
- KANSL1 | c.3194G>T p.R1065L (on ENST00000574590 / NM_001193465.2; = p.R1066L on NM_015443.4) | Missense Mutation (SNP) | VAF 37/46 reads (80%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52237183; called by muse, mutect2, varscan2
- KCND2 | c.1685G>C p.R562T | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.062); catalogued as rs1249044956, COSV58570086; called by muse, mutect2, varscan2
- KCNK3 | c.419T>G p.L140R | Missense Mutation (SNP) | VAF 48/52 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV57191566; called by muse, mutect2, varscan2
- KDM5A | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 28/51 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1362895739, CM118340, COSV66991075; called by muse, mutect2
- KIAA0513 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 32/111 reads (29%) | catalogued as COSV50740634; called by muse, mutect2, varscan2
- KIF14 | c.461A>G p.N154S | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV66259907; called by muse, mutect2, varscan2
- KNG1 | c.904G>T p.D302Y | Missense Mutation (SNP) | VAF 41/278 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV53976122; called by muse, mutect2, varscan2
- KPNA4 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 29/35 reads (83%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV62074748; called by muse, mutect2, varscan2
- LAMA1 | c.1681C>A p.Q561K | Missense Mutation (SNP) | VAF 64/180 reads (36%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV67532478; called by muse, varscan2
- LAMA1 | c.1680G>A p.M560I | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV67532481; called by muse, varscan2
- LAMP5 | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 55/136 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1179915173, COSV55715132; called by muse, mutect2, varscan2
- LCT | c.3466C>A p.H1156N | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV51544493; called by muse, mutect2, varscan2
- LHCGR | c.1988G>C p.C663S | Missense Mutation (SNP) | VAF 72/754 reads (10%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV54292909; called by muse, mutect2, varscan2
- LMBRD2 | c.892A>G p.S298G | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs756041545, COSV56948752; called by muse, mutect2, varscan2
- LPIN2 | c.1144G>T p.V382L | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as COSV55237405; called by muse, mutect2, varscan2
- LRPPRC | c.1625G>T p.S542I | Missense Mutation (SNP) | VAF 162/307 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as COSV53234427; called by muse, mutect2, varscan2
- LTV1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 162/208 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV52785521; called by muse, mutect2, varscan2
- LZTS1 | c.537G>C p.M179I | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.292); catalogued as COSV56115849; called by muse, mutect2, varscan2
- MAP2K6 | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 120/132 reads (91%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV63005129; called by muse, mutect2
- MAPKAPK2 | c.506G>T p.S169I | Missense Mutation (SNP) | VAF 422/503 reads (84%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.484); catalogued as COSV54314435; called by muse, mutect2, varscan2
- MARCO | c.570C>T p.G190= | Splice Region (SNP) | VAF 19/33 reads (58%) | catalogued as rs1441441936, COSV59051976; called by muse, mutect2, varscan2
- MBTPS1 | c.1804A>C p.T602P | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.034); catalogued as COSV58569456; called by muse, mutect2, varscan2
- MCTP1 | c.1860C>A p.H620Q | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1346692237, COSV56504910; called by muse, mutect2, varscan2
- MINAR1 | c.1301G>T p.G434V | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV59580970; called by muse, mutect2, varscan2
- MRPL51 | c.382C>T p.R128* | Nonsense Mutation (SNP) | VAF 22/84 reads (26%) | catalogued as rs758770414, COSV57519447; called by muse, mutect2, varscan2
- MSR1 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 86/156 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV50506996; called by muse, varscan2
- MUC16 | c.29285T>A p.L9762H | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.85); catalogued as COSV67446601; called by muse, mutect2, varscan2
- MUC16 | c.11560G>A p.G3854R | Missense Mutation (SNP) | VAF 101/170 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.087); catalogued as COSV67446605; called by muse, mutect2, varscan2
- MYBPC1 | c.2506C>G p.P836A (on ENST00000550270 / NM_206820.2; = p.P843A on NM_002465.4) | Missense Mutation (SNP) | VAF 63/253 reads (25%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV62251175; called by muse, mutect2, varscan2
- NCKAP1 | c.1910T>C p.I637T | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.268); catalogued as COSV62939872; called by muse, mutect2, varscan2
- NDN | c.551G>A p.R184H | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.015); catalogued as rs765248776, COSV59358232; called by muse, mutect2, varscan2
- NELL2 | c.1826G>T p.G609V | Missense Mutation (SNP) | VAF 96/181 reads (53%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.844); catalogued as COSV61569557; called by muse, mutect2, varscan2
- NMRK1 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 45/111 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1027865360, COSV63111643; called by muse, mutect2, varscan2
- NOD2 | c.538A>T p.R180W | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV56048441; called by muse, mutect2, varscan2
- NPS | c.226G>C p.G76R | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV67690486; called by muse, mutect2
- NPY1R | c.988G>C p.D330H | Missense Mutation (SNP) | VAF 103/122 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56713356, COSV56713557; called by muse, mutect2, varscan2
- NRP2 | c.2270G>A p.G757E | Missense Mutation (SNP) | VAF 123/191 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55923663; called by muse, mutect2, varscan2
- OR10A7 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.068); catalogued as rs138358769, COSV100406485; called by muse, mutect2, varscan2
- OR10J3 | c.540T>A p.C180* | Nonsense Mutation (SNP) | VAF 158/331 reads (48%) | catalogued as COSV59953646; called by muse, mutect2, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 22/92 reads (24%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1C1 | c.178T>A p.Y60N | Missense Mutation (SNP) | VAF 133/160 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68715392; called by muse, mutect2, varscan2
- OR2T4 | c.436C>G p.L146V | Missense Mutation (SNP) | VAF 423/481 reads (88%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as COSV63543380; called by muse, mutect2, varscan2
- OR2T8 | c.889G>A p.G297R | Missense Mutation (SNP) | VAF 386/440 reads (88%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.816); catalogued as rs1208698913, COSV60661569; called by muse, mutect2, varscan2
- OR56A4 | c.719C>T p.S240F | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs116778909, COSV58109297; called by muse, mutect2, varscan2
- OR5F1 | c.575C>A p.T192K | Missense Mutation (SNP) | VAF 102/263 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV53545327; called by muse, mutect2, varscan2
- OR6K2 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 104/227 reads (46%) | catalogued as COSV62743128; called by muse, mutect2, varscan2
- OTOP2 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 164/196 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749488014, COSV58883538; called by muse, varscan2
- PAN2 | c.3608G>T p.*1203Lext*41 (on ENST00000425394 / NM_001127460.3; = p.*1199Lext*41 on NM_014871.5) | Nonstop Mutation (SNP) | VAF 33/59 reads (56%) | catalogued as COSV56263869; called by muse, mutect2, varscan2
- PAOX | c.1297A>C p.T433P | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV53371113; called by muse, mutect2, varscan2
- PAPPA2 | c.4343G>C p.C1448S | Missense Mutation (SNP) | VAF 144/159 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62791209; called by muse, mutect2, varscan2
- PDE10A | c.936C>A p.D312E | Missense Mutation (SNP) | VAF 79/92 reads (86%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); catalogued as rs1360974603, COSV63091504, COSV63094741; called by muse, mutect2, varscan2
- PHF20L1 | c.23G>T p.R8L | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV55188998, COSV55192890; called by muse, mutect2, varscan2
- PHTF1 | c.360G>T p.M120I | Missense Mutation (SNP) | VAF 73/127 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.048); catalogued as COSV63366845; called by muse, mutect2, varscan2
- PIK3C2B | c.4834C>T p.R1612* | Nonsense Mutation (SNP) | VAF 76/82 reads (93%) | catalogued as rs373485341; called by muse, mutect2, varscan2
- PIK3CG | c.1085G>C p.R362T | Missense Mutation (SNP) | VAF 152/345 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV63245685; called by muse, mutect2, varscan2
- PLEKHG4 | c.272C>G p.S91* | Nonsense Mutation (SNP) | VAF 6/21 reads (29%) | catalogued as COSV64611816; called by muse, mutect2, varscan2
- PLEKHH2 | c.230C>G p.T77S | Missense Mutation (SNP) | VAF 41/61 reads (67%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV56749946; called by muse, mutect2, varscan2
- PLEKHM3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 187/362 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV66815628; called by muse, mutect2, varscan2
- PLSCR5 | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 231/665 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as rs761966141, COSV71648929; called by muse, mutect2, varscan2
- PNLIPRP2 | c.321C>A p.D107E | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV53942272; called by muse, mutect2, varscan2
- PNLIPRP3 | c.548G>T p.G183V | Missense Mutation (SNP) | VAF 52/219 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); catalogued as COSV65047114; called by muse, mutect2, varscan2
- POPDC2 | c.1015A>G p.R339G | Missense Mutation (SNP) | VAF 70/161 reads (43%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0); catalogued as COSV51739804; called by muse, mutect2, varscan2
- POU6F1 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as rs1229420227, COSV61325911; called by muse, mutect2, varscan2
- PPP1R13L | c.731G>A p.R244Q | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.641); catalogued as rs767274852, COSV62907905; called by muse, mutect2, varscan2
- PRMT2 | c.479G>T p.R160L | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.206); catalogued as COSV52454231, COSV52457620; called by muse, mutect2, varscan2
- PTPRB | c.4888A>G p.I1630V | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.114); catalogued as COSV54233015; called by muse, mutect2, varscan2
- PTPRJ | c.641G>T p.R214L | Missense Mutation (SNP) | VAF 33/42 reads (79%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV69249930; called by muse, mutect2, varscan2
- PTX3 | c.859G>C p.G287R | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as COSV55821189; called by muse, mutect2, varscan2
- PUS10 | c.100C>G p.H34D | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as COSV57450642; called by muse, mutect2, varscan2
- QRFPR | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV57675360; called by muse, mutect2, varscan2
- RDH13 | c.577A>G p.K193E (on ENST00000415061 / NM_001145971.2; = p.K122E on NM_138412.4) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.039); catalogued as COSV52559669; called by muse, mutect2, varscan2
- RGL3 | c.1514C>A p.P505Q | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748616435, COSV66506503; called by muse, mutect2, varscan2
- ROR1 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.192); catalogued as rs1026892288, COSV64284126; called by muse, mutect2, varscan2
- RP1L1 | c.3151G>A p.V1051I | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as COSV66751971; called by muse, mutect2, varscan2
- RPGRIP1L | c.663G>C p.Q221H | Missense Mutation (SNP) | VAF 58/169 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.017); catalogued as COSV50902785; called by muse, mutect2, varscan2
- RPL19 | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 25/135 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV56634854; called by muse, mutect2, varscan2
- RUFY3 | c.236G>T p.S79I | Missense Mutation (SNP) | VAF 287/1693 reads (17%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.999); catalogued as COSV56911426; called by muse, mutect2, varscan2
- RYR2 | c.12961G>A p.G4321S | Missense Mutation (SNP) | VAF 277/305 reads (91%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.642); catalogued as COSV63657690, COSV63663924; called by muse, mutect2, varscan2
- SALL1 | c.3529C>T p.L1177F | Missense Mutation (SNP) | VAF 31/64 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); catalogued as COSV51753577; called by muse, mutect2, varscan2
- SI | c.3491G>T p.G1164V | Missense Mutation (SNP) | VAF 89/604 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.8); catalogued as COSV52266839; called by muse, mutect2, varscan2
- SLC39A12 | c.533C>A p.S178Y | Missense Mutation (SNP) | VAF 63/200 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.878); catalogued as COSV66195342, COSV66201085; called by muse, mutect2, varscan2
- SLC39A12 | c.1295C>A p.A432D | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT tolerated (0.27); PolyPhen benign (0.123); catalogued as rs778543774, COSV66195357; called by muse, mutect2, varscan2
- SLC4A10 | c.2195T>A p.L732Q (on ENST00000446997 / NM_001354461.2; = p.L702Q on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 164/275 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55765460; called by muse, mutect2, varscan2
- SLC5A11 | c.1844C>T p.S615F | Missense Mutation (SNP) | VAF 31/458 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as COSV61741171; called by muse, mutect2
- SLC5A12 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 135/319 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV54819154, COSV99745675; called by muse, mutect2, varscan2
- SLCO4C1 | c.827T>C p.L276S | Missense Mutation (SNP) | VAF 289/512 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as rs752601767, COSV60512942; called by muse, mutect2, varscan2
- SLITRK4 | c.1838G>T p.G613V | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.909); catalogued as COSV62022272; called by muse, mutect2, varscan2
- SLX4 | c.611G>A p.R204H | Missense Mutation (SNP) | VAF 43/91 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410797507, COSV53561106; called by muse, mutect2, varscan2
- SOX5 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 49/161 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.155); catalogued as COSV100507195, COSV58619338; called by muse, mutect2, varscan2
- SPAG11B | c.281G>T p.R94I | Missense Mutation (SNP) | VAF 73/291 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV52498836; called by muse, mutect2, varscan2
- SPATA31D1 | c.35C>A p.T12N | Missense Mutation (SNP) | VAF 132/345 reads (38%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV61192965; called by muse, mutect2, varscan2
- SPATA31D1 | c.1595T>A p.F532Y | Missense Mutation (SNP) | VAF 202/224 reads (90%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61192982; called by muse, mutect2, varscan2
- SPHKAP | c.2380A>G p.K794E | Missense Mutation (SNP) | VAF 308/520 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.044); catalogued as COSV60869227; called by muse, mutect2, varscan2
- SPTA1 | c.5526del p.V1843Sfs*9 | Frame Shift Del (DEL) | VAF 355/825 reads (43%) | catalogued as COSV63752779; called by mutect2, varscan2
- SPTA1 | c.1072C>A p.L358M | Missense Mutation (SNP) | VAF 367/672 reads (55%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); catalogued as COSV63749295; called by muse, mutect2, varscan2
- SRRM2 | c.1803G>T p.R601S | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV57068673; called by muse, mutect2, varscan2
- SSH2 | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 93/108 reads (86%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.318); catalogued as COSV52166902; called by muse, mutect2, varscan2
- SYMPK | c.226-2A>G p.X76_splice | Splice Site (SNP) | VAF 102/261 reads (39%) | catalogued as COSV55609755; called by muse, mutect2, varscan2
- TAF1 | c.668G>A p.R223H (on ENST00000373790 / NM_138923.4; = p.R244H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs765568995, COSV52107834; called by muse, mutect2, varscan2
- TAS2R40 | c.752A>G p.Y251C | Missense Mutation (SNP) | VAF 212/465 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as COSV68818111; called by muse, mutect2, varscan2
- TASP1 | c.851A>G p.Y284C | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.198); catalogued as rs1351927276, COSV61811490; called by muse, mutect2, varscan2
- TEX55 | c.1016A>T p.H339L | Missense Mutation (SNP) | VAF 142/339 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV55210135, COSV55210325; called by muse, mutect2, varscan2
- TMEM106B | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.998); catalogued as COSV67543372; called by muse, mutect2, varscan2
- TMPRSS12 | c.416C>T p.T139I | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.038); catalogued as COSV68255806; called by muse, mutect2, varscan2
- TNF | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 12/241 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.166); catalogued as rs1298153213, COSV69304184; called by muse, mutect2
- TNIK | c.1861G>A p.G621R | Missense Mutation (SNP) | VAF 84/517 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV52674271; called by muse, mutect2, varscan2
- TRIT1 | c.349A>G p.I117V | Missense Mutation (SNP) | VAF 26/40 reads (65%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.557); catalogued as rs760669230, COSV57547148; called by muse, varscan2
- TTN | c.69823G>C p.V23275L (on ENST00000591111; = p.V15851L on NM_003319.4) | Missense Mutation (SNP) | VAF 32/115 reads (28%) | PolyPhen benign (0); catalogued as COSV59899738; called by muse, mutect2, varscan2
- TTN | c.8702T>A p.F2901Y (on ENST00000591111; = p.F2855Y on NM_003319.4) | Missense Mutation (SNP) | VAF 50/168 reads (30%) | PolyPhen probably damaging (0.915); catalogued as COSV59899765; called by muse, mutect2, varscan2
- TTYH1 | c.776G>A p.G259D | Missense Mutation (SNP) | VAF 33/55 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV56609779; called by muse, mutect2, varscan2
- UBQLNL | c.1141C>A p.P381T | Missense Mutation (SNP) | VAF 132/265 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); catalogued as COSV66492668; called by muse, mutect2, varscan2
- UPF2 | c.1618G>A p.A540T | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV62658488; called by muse, mutect2, varscan2
- UQCRC2 | c.908G>A p.S303N | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV51670818, COSV51672257; called by muse, mutect2, varscan2
- USH2A | c.4662A>T p.E1554D | Missense Mutation (SNP) | VAF 148/170 reads (87%) | SIFT tolerated (0.95); PolyPhen benign (0.018); catalogued as COSV56330738; called by muse, mutect2, varscan2
- USP37 | c.1642G>T p.V548F | Missense Mutation (SNP) | VAF 79/138 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV51441462, COSV51446779; called by muse, mutect2, varscan2
- VAC14 | c.697C>T p.R233C | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs184943022, COSV55750781; called by mutect2, varscan2
- VAV1 | c.1624C>G p.Q542E | Missense Mutation (SNP) | VAF 116/205 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV58379005; called by muse, mutect2, varscan2
- WDR36 | c.1449C>G p.Y483* | Nonsense Mutation (SNP) | VAF 49/78 reads (63%) | catalogued as COSV72411039; called by muse, mutect2, varscan2
- ZBTB45 | c.671A>T p.E224V | Missense Mutation (SNP) | VAF 211/371 reads (57%) | SIFT tolerated (0.13); PolyPhen benign (0.203); catalogued as COSV54018083; called by muse, mutect2, varscan2
- ZCCHC7 | c.492G>C p.E164D | Missense Mutation (SNP) | VAF 197/239 reads (82%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as COSV100383483, COSV59718577; called by muse, mutect2, varscan2
- ZEB1 | c.2203C>T p.L735F | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58036900; called by muse, mutect2, varscan2
- ZFHX4 | c.863G>T p.G288V | Missense Mutation (SNP) | VAF 93/166 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760824197, COSV50508042; called by muse, mutect2, varscan2
- ZFP14 | c.1354T>C p.Y452H | Missense Mutation (SNP) | VAF 82/303 reads (27%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV54201078; called by muse, mutect2, varscan2
- ZFP90 | c.211G>C p.E71Q | Missense Mutation (SNP) | VAF 182/477 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.462); catalogued as COSV68050633; called by muse, mutect2, varscan2
- ZNF30 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57852658; called by muse, mutect2, varscan2
- ZNF423 | c.712G>T p.G238C (on ENST00000563137 / NM_001379286.1; = p.G230C on NM_015069.4) | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52178288; called by muse, mutect2, varscan2
- ZNF44 | c.1304A>T p.H435L (on ENST00000356109 / NM_001164276.2; = p.H387L on NM_016264.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61134726; called by muse, mutect2, varscan2
- ZNF536 | c.460G>C p.G154R | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62818959; called by muse, mutect2, varscan2
- ZNF548 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 124/282 reads (44%) | catalogued as COSV60240345; called by muse, mutect2, varscan2
- ZNF607 | c.1687T>C p.C563R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs146672126, COSV67696199; called by muse, mutect2, varscan2
- ZNF836 | c.1223A>G p.H408R | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59081184; called by muse, mutect2
- ADGRD1 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); called by muse, mutect2
- AP002748.5 | c.492_500dup p.Q165_P167dup | In Frame Ins (INS) | VAF 24/220 reads (11%) | called by mutect2, varscan2
- AVIL | c.2273_2274del p.Y758Lfs*16 | Frame Shift Del (DEL) | VAF 65/247 reads (26%) | called by pindel, varscan2
- DOCK5 | c.872G>T p.R291L | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- GCDH | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 108/186 reads (58%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- GDF2 | c.797A>G p.K266R | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- KCNT2 | c.3173del p.N1058Ifs*3 | Frame Shift Del (DEL) | VAF 142/218 reads (65%) | called by mutect2, pindel, varscan2
- MECOM | c.1440dup p.A481Cfs*2 (on ENST00000468789 / NM_001105078.4; = p.A669Cfs*2 on NM_004991.4) | Frame Shift Ins (INS) | VAF 127/511 reads (25%) | called by mutect2, pindel, varscan2
- OR8B8 | c.698del p.G233Afs*13 | Frame Shift Del (DEL) | VAF 403/683 reads (59%) | called by mutect2, pindel, varscan2
- SLC4A4 | c.3060del p.K1022Rfs*37 (on ENST00000264485 / NM_001098484.3; = p.K978Rfs*37 on NM_003759.4) | Frame Shift Del (DEL) | VAF 20/140 reads (14%) | called by mutect2, pindel, varscan2
- SLITRK2 | c.570del p.N191Ifs*3 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- SNTG2 | c.804del p.W268Cfs*12 | Frame Shift Del (DEL) | VAF 34/38 reads (89%) | called by mutect2, varscan2
- SPATA31A1 | c.392C>G p.P131R | Missense Mutation (SNP) | VAF 213/265 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SPTBN2 | c.5122_5131del p.Q1708Rfs*19 | Frame Shift Del (DEL) | VAF 16/47 reads (34%) | called by mutect2, pindel, varscan2
- TTN | c.731_739del p.A244_Q247delinsE | In Frame Del (DEL) | VAF 38/82 reads (46%) | called by mutect2, pindel*, varscan2
- ZW10 | c.1715C>T p.A572V | Missense Mutation (SNP) | VAF 9/218 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.056); called by muse, mutect2
- AMACR | c.450G>T p.L150= | Silent (SNP) | VAF 19/78 reads (24%) | catalogued as COSV59459774; called by muse, mutect2, varscan2
- ANO4 | c.303G>A p.V101= (on ENST00000392977 / NM_001286615.2; = p.V66= on NM_178826.4) | Silent (SNP) | VAF 94/174 reads (54%) | catalogued as rs775343966, COSV54586298; called by muse, mutect2, varscan2
- ATP2B2 | c.2145G>T p.T715= (on ENST00000352432; = p.T681= on NM_001683.5) | Silent (SNP) | VAF 47/72 reads (65%) | catalogued as rs768888914, COSV59489907, COSV59495553; called by muse, mutect2, varscan2
- BCL2L2 | c.276C>T p.N92= | Silent (SNP) | VAF 15/26 reads (58%) | catalogued as COSV51635488; called by muse, mutect2, varscan2
- BNIP2 | c.147G>A p.V49= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as COSV51105123; called by muse, mutect2, varscan2
- CATSPER1 | c.2160G>A p.L720= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV56409072; called by muse, mutect2, varscan2
- CCDC62 | c.2046C>T p.V682= | Silent (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- CDK12 | c.1455G>A p.E485= | Silent (SNP) | VAF 284/461 reads (62%) | catalogued as COSV70999386; called by muse, mutect2, varscan2
- CNGA4 | c.324C>T p.R108= | Silent (SNP) | VAF 188/360 reads (52%) | catalogued as rs1291444342, COSV66005130; called by muse, varscan2
- CNTNAP2 | c.2403C>A p.A801= | Silent (SNP) | VAF 100/232 reads (43%) | catalogued as COSV62147863; called by muse, mutect2, varscan2
- CORIN | c.1524C>T p.F508= | Silent (SNP) | VAF 58/133 reads (44%) | catalogued as COSV56686640; called by muse, mutect2, varscan2
- CTNND2 | c.1923G>C p.L641= | Silent (SNP) | VAF 233/438 reads (53%) | catalogued as COSV58866972; called by muse, mutect2, varscan2
- DLGAP3 | c.1965C>T p.F655= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as COSV52391623; called by muse, mutect2, varscan2
- DOCK5 | c.873G>T p.R291= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2
- EPB41L3 | c.976C>A p.R326= | Silent (SNP) | VAF 153/328 reads (47%) | catalogued as COSV59445208, COSV59460193; called by muse, mutect2, varscan2
- FLNA | c.3060G>A p.V1020= | Silent (SNP) | VAF 7/14 reads (50%) | called by muse, mutect2, varscan2
- GAA | c.1746C>T p.A582= | Silent (SNP) | VAF 39/45 reads (87%) | catalogued as COSV56406976; called by muse, mutect2, varscan2
- GRIN2B | c.2526C>T p.F842= | Silent (SNP) | VAF 84/151 reads (56%) | catalogued as rs867624672, COSV74204847; called by muse, mutect2, varscan2
- HELT | c.51G>C p.V17= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV58819624; called by muse, mutect2
- IGHG1 | c.591G>A p.L197= | Silent (SNP) | VAF 270/616 reads (44%) | called by muse, mutect2, varscan2
- ITGB2 | c.22C>T p.L8= | Silent (SNP) | VAF 16/23 reads (70%) | catalogued as COSV56607872; called by muse, mutect2, varscan2
- ITSN1 | c.996A>G p.E332= | Silent (SNP) | VAF 25/83 reads (30%) | catalogued as COSV66080895; called by muse, mutect2, varscan2
- KATNIP | c.3687T>G p.T1229= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as rs1386193170, COSV55173963; called by muse, mutect2, varscan2
- KCNH7 | c.3109C>T p.L1037= | Silent (SNP) | VAF 14/265 reads (5%) | catalogued as COSV59814884; called by muse, mutect2
- KCNK3 | c.418C>T p.L140= | Silent (SNP) | VAF 47/52 reads (90%) | catalogued as rs755486166, COSV57191559; called by muse, mutect2, varscan2
- KCTD9 | c.24G>A p.L8= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV55339287; called by muse, mutect2
- LRGUK | c.951G>A p.L317= | Silent (SNP) | VAF 54/150 reads (36%) | catalogued as COSV53634282; called by muse, mutect2, varscan2
- LRRC2 | c.798C>G p.L266= | Silent (SNP) | VAF 37/48 reads (77%) | catalogued as rs968173384, COSV56124990; called by muse, mutect2, varscan2
- LRRC7 | c.696T>C p.N232= (on ENST00000651989 / NM_001370785.2; = p.N199= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as rs1387378558, COSV50413331; called by muse, varscan2
- MAPKAPK2 | c.507C>T p.S169= | Silent (SNP) | VAF 421/503 reads (84%) | catalogued as COSV54314456; called by muse, mutect2, varscan2
- MAS1L | c.621A>G p.V207= | Silent (SNP) | VAF 147/154 reads (95%) | catalogued as COSV65808502; called by muse, mutect2, varscan2
- MASP1 | c.1989G>A p.V663= | Silent (SNP) | VAF 134/398 reads (34%) | catalogued as rs1248826715, COSV61824321; called by muse, mutect2, varscan2
- MDGA2 | c.2283G>A p.G761= (on ENST00000399232 / NM_001113498.2; = p.G463= on NM_182830.4) | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs759454328, COSV62079914; called by muse, mutect2, varscan2
- MROH5 | c.597C>T p.H199= | Silent (SNP) | VAF 6/12 reads (50%) | catalogued as COSV71300524; called by muse, mutect2, varscan2
- MUC16 | c.1974G>T p.T658= | Silent (SNP) | VAF 576/922 reads (62%) | catalogued as rs772586153, COSV101200366, COSV67446611; called by muse, mutect2, varscan2
- NUTM1 | c.3223C>A p.R1075= | Silent (SNP) | VAF 12/49 reads (24%) | catalogued as COSV59215827, COSV59218697; called by muse, varscan2
- OPN5 | c.861C>A p.L287= | Silent (SNP) | VAF 239/274 reads (87%) | catalogued as COSV55244287; called by muse, mutect2, varscan2
- OR2M2 | c.876C>T p.L292= | Silent (SNP) | VAF 127/585 reads (22%) | catalogued as COSV62897844; called by muse, mutect2, varscan2
- OR7G3 | c.675C>T p.V225= | Silent (SNP) | VAF 60/265 reads (23%) | catalogued as COSV59639902; called by muse, mutect2, varscan2
- PCDH11X | c.87C>A p.T29= | Silent (SNP) | VAF 60/71 reads (85%) | catalogued as COSV53444581; called by muse, mutect2, varscan2
- PCLO | c.10341G>T p.T3447= | Silent (SNP) | VAF 142/296 reads (48%) | catalogued as COSV61615170, COSV61629759; called by muse, mutect2, varscan2
- PKHD1L1 | c.2997A>T p.L999= | Silent (SNP) | VAF 29/49 reads (59%) | catalogued as COSV65737613, COSV65745656; called by muse, mutect2, varscan2
- PKHD1L1 | c.12417T>C p.S4139= | Silent (SNP) | VAF 75/303 reads (25%) | catalogued as COSV65737621; called by muse, mutect2, varscan2
- PLAG1 | c.1005G>A p.P335= | Silent (SNP) | VAF 101/155 reads (65%) | catalogued as rs150353769; called by muse, mutect2, varscan2
- PLXNA4 | c.3732G>T p.V1244= | Silent (SNP) | VAF 22/37 reads (59%) | called by muse, mutect2
- PTPRH | c.2445C>T p.D815= | Silent (SNP) | VAF 53/248 reads (21%) | called by muse, mutect2, varscan2
- RNASE3 | c.163C>A p.R55= | Silent (SNP) | VAF 153/343 reads (45%) | catalogued as rs115812876, COSV58959154; called by muse, mutect2, varscan2
- SCARB1 | c.819G>A p.E273= | Silent (SNP) | VAF 35/125 reads (28%) | catalogued as COSV55544282; called by muse, mutect2, varscan2
- SFMBT2 | c.1917G>A p.L639= | Silent (SNP) | VAF 54/106 reads (51%) | catalogued as COSV62805629; called by muse, mutect2, varscan2
- SLC16A2 | c.462C>A p.I154= | Silent (SNP) | VAF 94/115 reads (82%) | catalogued as COSV52082703; called by muse, mutect2, varscan2
- SLC26A4 | c.2292G>T p.T764= | Silent (SNP) | VAF 67/178 reads (38%) | catalogued as COSV55914548; called by muse, mutect2, varscan2
- SLITRK1 | c.546C>G p.L182= | Silent (SNP) | VAF 64/79 reads (81%) | catalogued as COSV65674380, COSV65677407; called by muse, mutect2, varscan2
- SPPL2B | c.339C>A p.R113= | Silent (SNP) | VAF 7/10 reads (70%) | catalogued as COSV66316756, COSV66316920, COSV66317183; called by muse, mutect2, varscan2
- SRD5A1 | c.360G>A p.A120= | Silent (SNP) | VAF 63/129 reads (49%) | catalogued as rs142854865; ClinVar: likely benign; called by muse, mutect2, varscan2
- TLK1 | c.1648C>T p.L550= | Silent (SNP) | VAF 76/124 reads (61%) | catalogued as rs756285074, COSV62629033; called by muse, mutect2, varscan2
- TLN2 | c.354T>C p.C118= | Silent (SNP) | VAF 69/188 reads (37%) | catalogued as COSV60885845; called by muse, mutect2, varscan2
- TMPRSS4 | c.531G>A p.R177= | Silent (SNP) | VAF 15/20 reads (75%) | catalogued as rs1565434490, COSV71108382; called by muse, mutect2, varscan2
- TRIP12 | c.4677C>T p.D1559= | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- TSLP | c.21A>G p.L7= | Silent (SNP) | VAF 221/361 reads (61%) | catalogued as rs149732987; called by muse, mutect2, varscan2
- TTC3 | c.63T>A p.P21= | Silent (SNP) | VAF 184/329 reads (56%) | catalogued as COSV61286139; called by muse, mutect2, varscan2
- UBC | c.438G>T p.V146= | Silent (SNP) | VAF 92/218 reads (42%) | catalogued as COSV60058285; called by muse, varscan2
- XIRP2 | c.274C>A p.R92= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as COSV54683865, COSV54731845; called by muse, mutect2, varscan2
- ZHX2 | c.978G>A p.V326= | Silent (SNP) | VAF 42/174 reads (24%) | catalogued as COSV58710429; called by muse, mutect2, varscan2
- ZNF250 | c.408G>A p.K136= | Silent (SNP) | VAF 41/218 reads (19%) | catalogued as rs1041468465, COSV52968011; called by muse, mutect2, varscan2
- ZNF285 | c.477C>A p.P159= | Silent (SNP) | VAF 79/218 reads (36%) | catalogued as COSV58408063; called by muse, mutect2, varscan2
- ZNF536 | c.3846T>A p.L1282= | Silent (SNP) | VAF 32/77 reads (42%) | catalogued as COSV62818967; called by muse, mutect2, varscan2
- ZNF559 | c.1614G>T p.V538= | Silent (SNP) | VAF 50/222 reads (23%) | catalogued as COSV57835014; called by muse, mutect2, varscan2
- ZSWIM5 | c.2143T>C p.L715= | Silent (SNP) | VAF 78/124 reads (63%) | catalogued as COSV62732643; called by muse, mutect2, varscan2
- CNTN3 | c.-1G>A | 5'UTR (SNP) | VAF 33/39 reads (85%) | catalogued as COSV55163752, COSV99723628; called by muse, mutect2, varscan2
- EI24P4 | n.888C>G | RNA (SNP) | VAF 603/1372 reads (44%) | called by muse, mutect2, varscan2
- OTUD6B | chr8:91070339 C>G | 5'Flank (SNP) | VAF 4/31 reads (13%) | catalogued as COSV53442038; called by muse, mutect2
- RMDN2 | c.452+21952C>G | Intron (SNP) | VAF 73/81 reads (90%) | catalogued as COSV99307354; called by muse, mutect2, varscan2
- SNORD115-20 | n.80C>T | RNA (SNP) | VAF 40/87 reads (46%) | called by muse, mutect2, varscan2
- TDRD10 | c.*142G>A | 3'UTR (SNP) | VAF 24/566 reads (4%) | called by muse, mutect2
